Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3955, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3955-01A (Primary Tumor).

Diagnosis:

1. and 3.: resected section of colon (descending and sigmoid colon) with tumor-free oral and aboral resection margins and including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the lamina muscularis propria, with several regional lymph node metastases (G2, pT2 L1 V0 R0 pN2a 5/31) and with distinctive, florid, perifocal inflammation (3.), encroaching on the peritoneum of the abdominal wall (1.).

Source: NCI Genomic Data Commons file 5da65a27-6478-48d2-96a2-13922a2669af (TCGA-AA-3955.20CB4D37-71CC-4CE2-A126-801EF9C251EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).